Surgical pathology report (de-identified scan), TCGA case TCGA-MQ-A4LP, project TCGA-MESO (Mesothelioma), tissue source site Washington University - NYU, specimen TCGA-MQ-A4LP-01A (Primary Tumor).

[page 1 of 4]
Result type:
Result date:
Result status:
Result title:

SPECIMEN DESCRIPTION

*** Final Report ***

SPECIMEN DESCRIPTION

PERICARDIAL FAT & PLEURA
DIAPHRAGMATIC PLEURA
LEVEL 4 LYMPH NODE (TRACHEOBRONCHIAL)
LEVEL 8 LYMPH NODE (PARAESOPHAGEAL)
LEVEL 7 LYMPH NODE (SUBCARINAL)
PLEURA
6TH RIB,
[REDACTED]

1CD-0-3
Mesothelioma, biphasic, Nos 9053/3
Site: pleura, Nos C38.4
lw
10/4/12

SURGICAL PATHOLOGY REPORT

LOCATION:

PATHOLOGY NO.
HOSPITAL ID

HOSPITAL NO.: [REDACTED]
ACCOUNT NO.: [REDACTED]
DATE RECEIVED:
DATE OF PROCEDURE:
ACCN REQ. NO.: NOT GIVEN

PATIENT'S NAME: [REDACTED]
AGE/SEX/DOB: M
PHYSICIAN(S):
COPY TO:

DIAGNOSIS:

- A. PERICARDIAL FAT AND PLEURA, EXCISION: MALIGNANT MESOTHELIOMA, BIPHASIC, INFILTRATING FIBROADIPOSE TISSUE WITH ASSOCIATED FIBRINOUS SEROSITIS.
- B. DIAPHRAGMATIC PLEURA: MALIGNANT MESOTHELIOMA, BIPHASIC INVADING FIBROCONNECTIVE TISSUE WITH ASSOCIATED ORGANIZING FIBRINOUS PLEURITIS AND HYALINE PLAQUE.
- C. LEVEL FOUR LYMPH NODE (TRACHEOBRONCHIAL), BIOPSY: MULTIPLE (FOUR) ANTHRACOTIC LYMPH NODES, NEGATIVE FOR METASTASES.
- D. LEVEL EIGHT LYMPH NODE (PARAESOPHAGEAL), BIOPSY: ONE ANTHRACOTIC LYMPH NODE, NEGATIVE FOR METASTASIS.
- E. LEVEL SEVEN LYMPH NODE (SUBCARINAL), BIOPSY: MULTIPLE (14) ANTHRACOTIC LYMPH NODES, NEGATIVE FOR METASTASIS.
- F. PLEURA, PLEURECTOMY: MALIGNANT MESOTHELIOMA, BIPHASIC, INFILTRATING

Printed by:
Printed on:

Page 1 of 4
(Continued)

[page 2 of 4]
FIBROCONNECTIVE TISSUE.

ADDENDUM: Special stains for immunohistochemistry are pending. An addendum will be issued with these results.

=====

SPECIMEN: A PERICARDIAL FAT & PLEURA
B DIAPHRAGMATIC PLEURA
C LEVEL 4 LYMPH NODE (TRACHEOBRONCHIAL)
D LEVEL 8 LYMPH NODE (PARAESOPHAGEAL)
E LEVEL 7 LYMPH NODE (SUBCARINAL)
F PLEURA
G 6TH RIB, [REDACTED]

OPERATION: RT THORACOTOMY, PLEURECTOMY
PRE-OP DIAGNOSIS: MESOTHELIOMA
POST-OP DIAGNOSIS: NOT GIVEN
CLINICAL DATA: NOT GIVEN

GROSS DESCRIPTION: Multiple parts.

Part A, received fresh labeled pericardial fat and pleura. The specimen consists of an irregular shaped portion of yellow lobulated glistening adipose tissue admixed with tan-pink fibrous tissue measuring 27 cm x 11 cm x 2.5 cm overall. One surface shows a glistening tan-pink membranous tissue. The opposite shows multiple nodules and pleural plaques ranging in size from 0.6 to 6 cm. Upon sectioning the nodules, the cut surface is tan-white firm and nodular, in areas becoming more glistening and fleshy, focal areas of necrosis are present. Representative sections are submitted in 5 cassettes. The section is submitted for frozen tumor bank.

Part B received fresh labeled diaphragmatic pleura. The specimen consists of two fragments of soft tissue. The largest fragment is 15 cm x 8 cm x 1 cm in maximum dimension, one surface is tan-pink and roughened with fibrous adhesions, the opposite side shows tan-white firm nodules, and plaque which range in size from 1 cm to 6 cm. Grossly, the mass does not appear to invade the skeletal muscle tissue. The second fragment of tissue is composed of a tan-pink glistening membranous tissue measuring 9 cm x 3.5 x 0.2 cm. The specimen has some firm nodularity present. Representative sections submitted as follows:

Cassettes 1-4-largest fragment,
Cassette 5-second fragment.

Part C received fresh labeled level 4 lymph node (tracheal bronchial), the specimen consists of an irregular portion of anthracotically pigmented lymph nodes and soft tissue measuring 3.5 x 1.2 x 1 cm. Specimen is submitted in toto in two cassettes.

Part D received fresh labeled level 8 lymph node. The specimen consists of a tan-brown rubbery lymph node measuring 1.2 x 0.4 x 0.2 cm. Specimen is submitted in toto in one cassette labeled D.

Printed by: [REDACTED]
Printed on:

Page 2 of 4
(Continued)

[page 3 of 4]
[REDACTED]

Part E received fresh labeled level 7 lymph node (subcarinal). The specimen consists of multiple fragments of anthracotically pigmented lymph nodes aggregating to 6 cm x 3 cm x 0.3 cm. Largest lymph node is fragmented, measures 2.5 x 1.2 x 1 cm. One of the fragments is composed of a yellow-tan calcified nodule measuring 0.6 x 0.4 x 0.3 cm.

Summary of sections is as follows:

Cassette 1-one lymph node,
Cassette 2-one lymph node,
Cassette 3-three lymph nodes,
Cassette 4-five lymph nodes,
Cassette 5-four lymph nodes
Cassette 6-five lymph nodes,
Cassette 7-largest lymph node, one half,
Cassette 8-second half of the largest lymph node.

Part F received fresh labeled pleura. The specimen consists of tan-pink glistening tissue on one surface, the opposite surface shows white-tan nodular plaque, the specimen measures 25 cm x 13 cm x 0.5 cm overall. Multiple nodules across this surface range in size from 0.1 to 12 cm, the 12 cm mass is a tan-white firm plaque. Second fragment of tissue is composed of a portion of soft tissue measuring 15 cm x 10 cm x 1 cm. One surface is tan-pink smooth and glistening, the opposite shows fibrous adhesions, the entire surface has a yellow-tan nodular plaque present. In addition, there is a separate tan-brown nodular mass that has been incised in multiple areas measuring 4 cm x 2 x 1 cm. Representative sections are submitted in 5 cassettes.

CPT CODE:

ELECTRONIC SIGNATURE:

SURGICAL PATHOLOGY REPORT

LOCATION:

HOSPITAL ID.: [REDACTED]

PATHOLOGY NO.: [REDACTED]

HOSPITAL NO.: [REDACTED]

PATIENT'S NAME: [REDACTED]

ACCOUNT NO.: [REDACTED]

AGE/SEX/DOB: M

DATE RECEIVED:

PHYSICIAN(S):

DATE OF PROCEDURE:

COPY TO:

ACCN REQ. NO.: NOT GIVEN

=====

ADDENDUM REPORT

~~Immunohistochemical stain support the diagnosis of malignant mesothelioma as~~
the proliferating cells are positive with cytokeratin, Wilm's tumor marker, calretinin, and thrombomodulin. They are negative with actin cytokeratin 5/6.

Printed by: [REDACTED]
Printed on:

Page 3 of 4
(Continued)

[page 4 of 4]
[REDACTED]

SPECIMEN: A PERICARDIAL FAT & PLEURA
B DIAPHRAGMATIC PLEURA
C LEVEL 4 LYMPH NODE (TRACHEOBRONCHIAL)
D LEVEL 8 LYMPH NODE (PARAESOPHAGEAL)
E LEVEL 7 LYMPH NODE (SUBCARINAL)
F PLEURA
G 6TH RIB, [REDACTED]

OPERATION: RT THORACOTOMY, PLEURECTOMY
PRE-OP DIAGNOSIS: MESOTHELIOMA
POST-OP DIAGNOSIS: NOT GIVEN
CLINICAL DATA: NOT GIVEN

CPT CODE: [REDACTED]
ELECTRONIC SIGNATURE: [REDACTED]

Completed Action List:

Printed by: [REDACTED]
Printed on: [REDACTED]

Page 4 of 4
(End of Report)

9/23/12

Source: NCI Genomic Data Commons file 707670fe-5cf0-497e-9a33-52217e3efc72 (TCGA-MQ-A4LP.43C3017A-16AC-4184-B2CE-68DFC3F81472.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).